CCDI case PBCRMF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/45c0695e-f6eb-4d97-87b6-5a520344a6f2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.3 years (7,060 days).

Biospecimens (3 samples)
- Sample 0DXJEM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXJF7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXJI2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
